Somatic mutation profile of tumor specimen C3N-02978-02 (aliquot CPT0244470006) from CPTAC case C3N-02978, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.2 years (24,162 days).
Specimen C3N-02978-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 153a712d-7f73-47f4-a078-c5ee420e9113.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02978-31 (Blood Derived Normal), aliquot CPT0244490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a37a004-2297-4402-8be3-3f06293b8b50

The open-access MAF lists 819 somatic variants for this specimen: 515 protein-altering or splice-affecting, 187 silent, 117 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 329, Silent 187, Frame Shift Del 103, Intron 62, Frame Shift Ins 37, Nonsense Mutation 22, 3'UTR 20, 5'UTR 14, RNA 12, In Frame Del 8, Splice Site 7, Splice Region 7.

Variants (750 of 819; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 29/66 reads (44%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- FOXP3 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | catalogued as rs1057517736, CM1510215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318dup p.S774Vfs*12 | Frame Shift Ins (INS) | VAF 48/438 reads (11%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 146/376 reads (39%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 168/483 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/144 reads (36%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ABCC8 | c.1818-6G>A | Splice Region (SNP) | VAF 134/351 reads (38%) | catalogued as rs368708177; called by muse, mutect2, varscan2
- ADAM2 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV99697666; called by muse, mutect2, varscan2
- ADAM8 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as rs551247898; called by muse, mutect2, varscan2
- ADAMTS17 | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs1244171699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL2 | c.2870G>A p.G957D (on ENST00000370717 / NM_001366005.1; = p.G944D on NM_012302.4) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs573957983; called by muse, mutect2, varscan2
- ADGRV1 | c.12490G>A p.E4164K | Missense Mutation (SNP) | VAF 146/386 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1357883094, COSV101315272; called by muse, mutect2, varscan2
- ADPGK | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 177/477 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs767756237; called by muse, mutect2, varscan2
- AEBP1 | c.786_788del p.R265del | In Frame Del (DEL) | VAF 23/91 reads (25%) | catalogued as rs768974633; called by mutect2, pindel, varscan2
- AGAP6 | c.868C>T p.L290F (on ENST00000374056 / NM_001365867.1; = p.L313F on NM_001077665.2) | Missense Mutation (SNP) | VAF 431/1244 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1554864726; called by muse, mutect2, varscan2
- AGPAT1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as rs1331273987; called by muse, mutect2, varscan2
- AHNAK | c.8362G>A p.V2788M | Missense Mutation (SNP) | VAF 161/422 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs143105736; called by muse, mutect2, varscan2
- AK5 | c.769C>T p.R257C (on ENST00000354567 / NM_174858.3; = p.R231C on NM_012093.4) | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745816196; called by muse, mutect2, varscan2
- AK9 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs369829767, COSV99572560; called by muse, mutect2
- AKR1C8P | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs555305935; called by muse, mutect2
- ANK1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 143/366 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1479278167; called by muse, mutect2, varscan2
- ANK1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 21/532 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1448156749, COSV99225369; called by muse, mutect2
- ANKRD27 | c.3080C>T p.A1027V | Missense Mutation (SNP) | VAF 172/452 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs770293349, COSV60132848; called by muse, mutect2, varscan2
- APOBEC3H | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.911); catalogued as rs769176395, COSV100818874; called by muse, mutect2, varscan2
- APPL1 | c.460dup p.R154Kfs*4 | Frame Shift Ins (INS) | VAF 23/151 reads (15%) | catalogued as rs749401724; called by mutect2, varscan2
- ARFGEF3 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs1342716926; called by muse, mutect2, varscan2
- ARHGEF17 | c.5194G>A p.V1732I | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs781033175; called by muse, mutect2, varscan2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 63/176 reads (36%) | catalogued as COSV61372766; called by mutect2, pindel, varscan2
- ARVCF | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as rs767204635; called by muse, mutect2, varscan2
- ASAP2 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs138272038; called by muse, mutect2
- ASIC3 | c.906dup p.S303Qfs*114 | Frame Shift Ins (INS) | VAF 89/286 reads (31%) | catalogued as rs1162782720; called by mutect2, pindel, varscan2
- ATG9B | c.2162del p.P721Qfs*62 | Frame Shift Del (DEL) | VAF 68/230 reads (30%) | catalogued as COSV52486004; called by mutect2, varscan2
- ATL3 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.542); catalogued as rs1028428171; called by muse, mutect2, varscan2
- ATP11A | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs372167641; called by muse, mutect2, varscan2
- ATP8B2 | c.1148G>A p.R383H (on ENST00000672630; = p.R350H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59244890, COSV59249005; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 21/159 reads (13%) | catalogued as rs752427670; called by mutect2, varscan2
- BMPER | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 270/680 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV51820399; called by muse, mutect2, varscan2
- BNIPL | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs587741752; called by muse, mutect2, varscan2
- BRAT1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.115); catalogued as rs780327501, COSV61395053; called by muse, mutect2, varscan2
- BRSK1 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 181/467 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs769516314, COSV58665178; called by muse, mutect2, varscan2
- C19orf44 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1489590370; called by muse, mutect2, varscan2
- C1orf167 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1178021719, COSV70596481; called by muse, mutect2, varscan2
- CACNA1G | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.312); catalogued as rs202055246, COSV61733022; called by muse, mutect2, varscan2
- CADM4 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 123/319 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758520204, COSV55928459; called by muse, mutect2, varscan2
- CCR6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 164/446 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs545727839; called by muse, mutect2, varscan2
- CD3E | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs143630318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD79A | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 270/661 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs782507150, COSV55739789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDCA2 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | catalogued as rs767647125, COSV57945898; called by muse, mutect2, varscan2
- CDH22 | c.1176del p.E393Sfs*24 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | catalogued as rs768497155, COSV64836926; called by mutect2, pindel
- CELSR1 | c.5669C>T p.A1890V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs917248715; called by muse, mutect2, varscan2
- CIITA | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 59/492 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs548646642, COSV60853941; called by muse, mutect2, varscan2
- CLEC12B | c.680+5G>A | Splice Region (SNP) | VAF 84/195 reads (43%) | catalogued as rs370229418; called by muse, mutect2, varscan2
- COLGALT1 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.208); catalogued as COSV53110411; called by muse, mutect2, varscan2
- COQ2 | c.1184dup p.L395Ffs*24 | Frame Shift Ins (INS) | VAF 45/124 reads (36%) | catalogued as rs763059203; called by mutect2, varscan2
- COX16 | c.165del p.K55Nfs*2 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs759241200; called by mutect2, varscan2
- COX7B2 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs775458548, COSV100260586; called by muse, mutect2
- CPB2 | c.653_654del p.Y218Cfs*6 | Frame Shift Del (DEL) | VAF 54/158 reads (34%) | catalogued as rs1375337086; called by mutect2, pindel, varscan2
- CPT1C | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs140642411; called by muse, mutect2, varscan2
- CSMD3 | c.9379C>T p.R3127* (on ENST00000297405 / NM_001363185.1; = p.R2958* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 116/305 reads (38%) | catalogued as COSV52211222; called by muse, mutect2, varscan2
- CYBC1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.891); catalogued as rs1337660914; called by muse, mutect2, varscan2
- CYTH3 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV100641711, COSV63440643; called by muse, mutect2, varscan2
- DCTN2 | c.952C>T p.R318C (on ENST00000548249 / NM_001261413.2; = p.R323C on NM_006400.4) | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1188405631; called by muse, varscan2
- DHRS12 | c.719C>T p.A240V (on ENST00000444610 / NM_001377930.1; = p.A191V on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs371510695; called by muse, mutect2, varscan2
- DLGAP1 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 170/492 reads (35%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.715); catalogued as rs752990499; called by muse, mutect2, varscan2
- DLGAP2 | c.393del p.R132Afs*15 | Frame Shift Del (DEL) | VAF 58/164 reads (35%) | catalogued as rs755665055, COSV101422687, COSV70099967; called by mutect2, varscan2
- DNAH8 | c.7379C>T p.T2460I | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543858; called by muse, mutect2, varscan2
- DND1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 105/701 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as COSV100298033, COSV56907901; called by muse, mutect2, varscan2
- DOCK6 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.91); catalogued as rs376149847; called by muse, mutect2, varscan2
- DRD4 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1224883465; called by muse, mutect2
- DSEL | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759651332; called by muse, mutect2
- DUOXA1 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 208/567 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as rs1276234731; called by muse, mutect2, varscan2
- EHD4 | c.1579del p.H527Tfs*37 | Frame Shift Del (DEL) | VAF 71/222 reads (32%) | catalogued as rs758354312; called by mutect2, pindel, varscan2
- EME2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 153/334 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as rs377368785; called by muse, mutect2, varscan2
- EPHA6 | c.1379G>A p.S460N | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs924630409; called by muse, mutect2
- ERICH4 | c.64del p.Q22Rfs*3 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as rs567420399; called by mutect2, pindel, varscan2
- ERMP1 | c.1951dup p.T651Nfs*25 | Frame Shift Ins (INS) | VAF 34/94 reads (36%) | catalogued as rs753821453; called by mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 118/314 reads (38%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI5L | c.2174G>T p.R725L | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV54487574; called by muse, mutect2, varscan2
- EWSR1 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs372053944; called by muse, mutect2, varscan2
- FAM20A | c.907_908del p.S303Cfs*76 | Frame Shift Del (DEL) | VAF 170/570 reads (30%) | catalogued as rs750880244; called by pindel, varscan2
- FBRS | c.1333del p.R445Gfs*41 (on ENST00000287468; = p.R965Gfs*41 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 25/169 reads (15%) | catalogued as COSV54916187; called by mutect2, pindel
- FICD | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as rs763250722, COSV57207724, COSV57208281; called by muse, mutect2
- FIGNL2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1434156162; called by muse, mutect2, varscan2
- FMO5 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142613638; called by muse, mutect2, varscan2
- FUZ | c.388-6T>A | Splice Region (SNP) | VAF 105/644 reads (16%) | catalogued as rs1009581560; called by muse, mutect2, varscan2
- FXN | c.80C>T p.T27M (on ENST00000377270; = p.T102M on NM_000144.5) | Missense Mutation (SNP) | VAF 172/469 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs964046026; called by muse, mutect2, varscan2
- GABRE | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as rs765563256, COSV64821466; called by muse, mutect2, varscan2
- GALNT17 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1279754066; called by muse, mutect2, varscan2
- GDA | c.715-2A>G p.X239_splice | Splice Site (SNP) | VAF 25/70 reads (36%) | catalogued as rs1191356874; called by muse, mutect2
- GDPD5 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100409554; called by muse, mutect2, varscan2
- GFPT1 | c.778G>A p.D260N (on ENST00000357308 / NM_001244710.2; = p.D242N on NM_002056.4) | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61950062; called by muse, mutect2, varscan2
- GIMAP7 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 198/517 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs865889109; called by muse, mutect2, varscan2
- GLI2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.609); catalogued as COSV58040825; called by muse, mutect2, varscan2
- GRIA3 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs750202196; called by muse, mutect2, varscan2
- GRIP2 | c.3274C>T p.R1092C (on ENST00000619221; = p.R995C on NM_001080423.4) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs759209816, COSV56119423; called by muse, mutect2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2F1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 132/358 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs748571217, COSV66726980; called by muse, varscan2
- HABP2 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs374241151, COSV100667891; called by muse, mutect2, varscan2
- HERC2 | c.9304C>T p.R3102W | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765532329; called by muse, mutect2, varscan2
- HERC2 | c.6115G>C p.V2039L | Missense Mutation (SNP) | VAF 210/562 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1378157705; called by muse, mutect2, varscan2
- HIC1 | c.1112del p.P371Rfs*82 (on ENST00000322941 / NM_001098202.1; = p.P352Rfs*82 on NM_006497.4) | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as rs1567557055; called by mutect2, pindel, varscan2
- HPS5 | c.1592G>A p.R531H (on ENST00000349215 / NM_181507.2; = p.R417H on NM_007216.4) | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs755697317; called by muse, mutect2
- HS3ST3A1 | c.528del p.D177Tfs*26 | Frame Shift Del (DEL) | VAF 139/460 reads (30%) | catalogued as COSV52375860; called by mutect2, pindel, varscan2
- HTR5A | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201595546; called by muse, mutect2, varscan2
- IDUA | c.1395del p.G466Afs*59 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs1386109118; called by mutect2, pindel, varscan2
- IGHM | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 291/756 reads (38%) | SIFT tolerated (1); catalogued as rs782080241; called by muse, mutect2, varscan2
- IL18RAP | c.1642A>G p.N548D | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs200096865; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 45/134 reads (34%) | catalogued as rs760925109; called by pindel, varscan2
- INSRR | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 224/795 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV104427273; called by muse, mutect2, varscan2
- IRX1 | c.190T>C p.Y64H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs1389148590; called by muse, mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 66/231 reads (29%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- JADE2 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1444960089; called by muse, mutect2, varscan2
- JAKMIP3 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.552); catalogued as rs943352446, COSV53820622; called by muse, mutect2, varscan2
- KBTBD11 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.038); catalogued as rs1196601865; called by muse, mutect2, varscan2
- KCNB1 | c.1781G>A p.C594Y | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65568637; called by muse, mutect2, varscan2
- KCNK3 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1461138996, COSV57194709; called by muse, mutect2, varscan2
- KIAA1841 | c.713T>A p.L238* | Nonsense Mutation (SNP) | VAF 65/142 reads (46%) | catalogued as rs977985059; called by muse, varscan2
- KIF5A | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 93/474 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV54051316; called by muse, mutect2, varscan2
- KLHL25 | c.1040del p.G347Afs*29 | Frame Shift Del (DEL) | VAF 30/238 reads (13%) | catalogued as rs760548052, COSV100563595; called by mutect2, pindel, varscan2
- L1CAM | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as COSV62827759; called by muse, mutect2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 57/156 reads (37%) | catalogued as rs780042765; called by mutect2, varscan2
- LMF2 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs767939021; called by muse, mutect2, varscan2
- LONP1 | c.442_444del p.K148del | In Frame Del (DEL) | VAF 45/161 reads (28%) | catalogued as rs1240151785; called by pindel, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | catalogued as rs757410385; called by mutect2, varscan2
- LRRC20 | c.547del p.L183Yfs*54 (on ENST00000355790 / NM_207119.3; = p.L127Yfs*54 on NM_018205.4) | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | catalogued as rs768741708; called by mutect2, pindel, varscan2
- MAGEL2 | c.2705C>T p.T902M | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.001); catalogued as rs373945272; called by mutect2, varscan2
- MAP1B | c.5901dup p.E1968Rfs*8 | Frame Shift Ins (INS) | VAF 49/156 reads (31%) | catalogued as rs775893760; called by mutect2, varscan2
- MCHR1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 217/549 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs550313335, CM106863, COSV50760512; called by muse, mutect2, varscan2
- MICAL1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 182/432 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs760656869; called by muse, mutect2, varscan2
- MKI67 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 64/233 reads (27%) | catalogued as rs370668284; called by muse, mutect2, varscan2
- MLNR | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 186/461 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs201256240; called by muse, mutect2, varscan2
- MORC2 | c.1886C>A p.P629H (on ENST00000397641 / NM_001303256.3; = p.P567H on NM_014941.3) | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs745722246; called by muse, mutect2
- MRI1 | c.874G>A p.G292S (on ENST00000040663 / NM_001031727.4; = p.G245S on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs923199210, COSV50005516; called by muse, mutect2, varscan2
- MS4A12 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV50014311, COSV99188741; called by muse, varscan2
- MTOR | c.6808C>T p.R2270W | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1266984212, COSV63874499; called by muse, mutect2
- MTOR | c.4550C>T p.A1517V | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV63871153; called by muse, mutect2, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 42/114 reads (37%) | catalogued as rs537060918; called by mutect2, varscan2
- MUC5B | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 116/276 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs367802099; called by muse, mutect2, varscan2
- MYL5 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs776201829; called by muse, mutect2, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NAP1L2 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65173062; called by muse, mutect2, varscan2
- NDRG1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1276408714; called by muse, mutect2, varscan2
- NOD2 | c.1515del p.S506Pfs*11 | Frame Shift Del (DEL) | VAF 27/138 reads (20%) | catalogued as rs754761524; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NSFL1C | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1451111789, COSV53795214; called by muse, mutect2, varscan2
- OR10H5 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as rs746677353, COSV58277366; called by muse, mutect2, varscan2
- OR12D2 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV65827669; called by muse, mutect2
- OR2M4 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV60708455; called by muse, mutect2, varscan2
- OR4D9 | c.326dup p.A110Sfs*12 | Frame Shift Ins (INS) | VAF 51/161 reads (32%) | catalogued as rs759093140; called by mutect2, pindel, varscan2
- PCDH8 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs373933829, COSV100131644; called by muse, mutect2
- PCDHA7 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 24/764 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as rs1401581496; called by muse, mutect2
- PCDHGA1 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 288/741 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as rs762152002, COSV65299810; called by muse, mutect2, varscan2
- PCDHGB5 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 79/622 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as rs1561672586; called by muse, mutect2, varscan2
- PCNT | c.6410del p.G2137Vfs*2 | Frame Shift Del (DEL) | VAF 59/457 reads (13%) | catalogued as COSV64032914; called by mutect2, pindel, varscan2
- PCYT2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777077762; called by muse, mutect2, varscan2
- PDE4B | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs752353754, COSV58475585; called by muse, mutect2, varscan2
- PDE6C | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139251833; called by muse, mutect2, varscan2
- PDPK1 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.429); catalogued as COSV51912351; called by muse, mutect2, varscan2
- PGR | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 49/147 reads (33%) | catalogued as rs1315135533, COSV54796997; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 88/210 reads (42%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PIH1D1 | c.743del p.G248Afs*8 | Frame Shift Del (DEL) | VAF 44/124 reads (35%) | catalogued as rs1274833333; called by mutect2, pindel
- PINX1 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100134846; called by muse, mutect2
- PPP4R1 | c.164C>A p.A55D (on ENST00000400556 / NM_001042388.3; = p.A38D on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53280638; called by muse, mutect2
- PRKAR1B | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs765662228, COSV100816490; called by muse, mutect2, varscan2
- PRMT8 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as rs1290294414, COSV54211906; called by muse, mutect2, varscan2
- PROKR1 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV58137995; called by muse, mutect2, varscan2
- PTEN | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 185/431 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as CD110165, CM110135, CX983284, COSV64289692, COSV64297668, COSV64311547; called by muse, mutect2, varscan2
- PTX4 | c.1191dup p.G398Rfs*? (on ENST00000447419 / NM_001328608.2; = p.G393Rfs*? on NM_001013658.1) | Frame Shift Ins (INS) | VAF 52/214 reads (24%) | catalogued as rs772722517; called by mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 57/137 reads (42%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAI1 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs752599214; called by muse, mutect2
- RAPGEF4 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 54/162 reads (33%) | catalogued as rs1045496711, COSV51398489; called by muse, mutect2, varscan2
- RASIP1 | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs367666886; called by muse, mutect2, varscan2
- RBM10 | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 193/547 reads (35%) | catalogued as COSV61309752; called by muse, mutect2, varscan2
- RECQL4 | c.3286C>T p.R1096C | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs371049072, COSV56743315; ClinVar: uncertain significance; called by muse, mutect2
- RGL2 | c.608dup p.S204Qfs*3 | Frame Shift Ins (INS) | VAF 69/220 reads (31%) | catalogued as rs762949421; called by mutect2, varscan2
- RIN1 | c.346_348del p.F116del | In Frame Del (DEL) | VAF 42/114 reads (37%) | catalogued as rs1565202523; called by mutect2, pindel, varscan2
- RLF | c.5479A>G p.I1827V | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs377537141; called by muse, mutect2, varscan2
- RNFT2 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 109/300 reads (36%) | catalogued as rs1332429686; called by muse, mutect2, varscan2
- RP1 | c.458del p.P153Hfs*4 | Frame Shift Del (DEL) | VAF 120/293 reads (41%) | catalogued as rs781249059; called by mutect2, varscan2
- RPS6KA1 | c.1817C>T p.T606I | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs770722105; called by muse, mutect2, varscan2
- RRNAD1 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs965092441; called by muse, mutect2, varscan2
- RTEL1 | c.2597G>A p.R866K | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs1316053268; called by muse, mutect2, varscan2
- RTKN2 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 134/365 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs757266154, COSV59523152; called by muse, mutect2, varscan2
- RTL1 | c.3653G>A p.R1218H | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs747974765; called by muse, mutect2, varscan2
- SCN5A | c.4299+1del p.X1433_splice (on ENST00000333535 / NM_198056.3; = p.X1432_splice on NM_000335.5) | Splice Site (DEL) | VAF 62/181 reads (34%) | catalogued as rs1450434935, CD094273, CS100773; called by mutect2, pindel, varscan2
- SEMA3B | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 150/362 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as rs1553706814, COSV57115966; called by muse, mutect2, varscan2
- SEMA4B | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1228184089; called by muse, mutect2
- SEPTIN11 | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV53580733; called by muse, mutect2, varscan2
- SF3A1 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776315877; called by muse, mutect2, varscan2
- SH3BP2 | c.429-4G>A | Splice Region (SNP) | VAF 73/198 reads (37%) | catalogued as rs766274844; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 58/181 reads (32%) | catalogued as rs746556543; called by mutect2, varscan2
- SLC25A10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs201235464; called by muse, mutect2, varscan2
- SLC37A3 | c.1325A>G p.Q442R | Missense Mutation (SNP) | VAF 186/482 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs755097083; called by muse, mutect2, varscan2
- SLC44A3 | c.1722del p.F574Lfs*4 (on ENST00000271227 / NM_001114106.3; = p.F526Lfs*4 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 148/499 reads (30%) | catalogued as rs752543591, COSV54732637; called by mutect2, pindel, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 31/218 reads (14%) | catalogued as rs768873484; called by mutect2, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 83/225 reads (37%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SOS1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 188/461 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.754); catalogued as rs867539471, COSV67675049; called by muse, mutect2, varscan2
- SOX1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.874); catalogued as rs1398178334; called by muse, mutect2, varscan2
- SPRED1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 150/352 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as rs1348585688, COSV54434997; called by muse, mutect2, varscan2
- SPTBN2 | c.4145C>T p.A1382V | Missense Mutation (SNP) | VAF 24/672 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1163559830; called by muse, mutect2
- SPX | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV57021313; called by muse, mutect2, varscan2
- SRSF5 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1332582034, COSV53683511; called by muse, mutect2
- STMN2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55218183, COSV55223296; called by muse, mutect2, varscan2
- STOX2 | c.94_96del p.K32del | In Frame Del (DEL) | VAF 78/222 reads (35%) | catalogued as rs1345014124; called by mutect2, pindel, varscan2
- SUSD3 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as rs1230644233; called by muse, mutect2, varscan2
- SYNE3 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 55/410 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as rs1488537327; called by muse, mutect2, varscan2
- SZT2 | c.7517G>A p.R2506Q (on ENST00000634258 / NM_001365999.1; = p.R2449Q on NM_015284.4) | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.307); catalogued as rs185048193, COSV100986838; called by muse, mutect2, varscan2
- SZT2 | c.8696C>T p.S2899L (on ENST00000634258 / NM_001365999.1; = p.S2842L on NM_015284.4) | Missense Mutation (SNP) | VAF 200/447 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs200453852, COSV65168882; called by muse, mutect2, varscan2
- TAF8 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs966434982, COSV65895671, COSV65896301; called by muse, mutect2, varscan2
- TAP2 | c.1220G>A p.G407D | Missense Mutation (SNP) | VAF 258/627 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100886957; called by muse, mutect2, varscan2
- TBC1D31 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs74653260; called by muse, mutect2, varscan2
- TBC1D8B | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 71/197 reads (36%) | catalogued as rs200526006, COSV99344166; called by muse, mutect2, varscan2
- TCAIM | c.786del p.A263Qfs*14 | Frame Shift Del (DEL) | VAF 19/180 reads (11%) | catalogued as rs1290149199; called by mutect2, pindel, varscan2
- TFAP2E | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs768908023; called by muse, mutect2, varscan2
- THSD7A | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs770553838; called by muse, mutect2, varscan2
- TLR10 | c.2256dup p.A753Sfs*9 | Frame Shift Ins (INS) | VAF 34/100 reads (34%) | catalogued as rs564674109; called by mutect2, varscan2
- TLR4 | c.1683dup p.Q562Tfs*9 (on ENST00000355622 / NM_138554.5; = p.Q522Tfs*9 on NM_003266.4) | Frame Shift Ins (INS) | VAF 104/312 reads (33%) | catalogued as rs759923416; called by mutect2, pindel, varscan2
- TNC | c.4574C>T p.T1525M | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as rs776659022; called by muse, mutect2, varscan2
- TOE1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs192575433, COSV59152777; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 94/222 reads (42%) | catalogued as rs770561785; called by mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | catalogued as rs756650873; called by mutect2, varscan2
- TTLL5 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs201637928; called by muse, mutect2, varscan2
- UBE2Q1 | c.101del p.G34Afs*8 | Frame Shift Del (DEL) | VAF 54/184 reads (29%) | catalogued as rs759160193; called by mutect2, varscan2
- UMOD | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs1162633293; called by muse, mutect2
- UPRT | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV100975815, COSV64919982; called by muse, mutect2, varscan2
- USP17L1 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 153/529 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs775204119, COSV73252924; called by muse, mutect2, varscan2
- USP53 | c.694del p.I232* | Frame Shift Del (DEL) | VAF 23/173 reads (13%) | catalogued as COSV56793483; called by mutect2, pindel, varscan2
- VGLL4 | c.466del p.E156Sfs*9 | Frame Shift Del (DEL) | VAF 124/349 reads (36%) | catalogued as rs1336506832; called by mutect2, pindel, varscan2
- VIT | c.919C>T p.R307W (on ENST00000389975 / NM_001177969.1; = p.R322W on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/303 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748465900, COSV64899029; called by muse, mutect2, varscan2
- VPS13D | c.12795-1G>A p.X4265_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as COSV50654920; called by muse, mutect2
- VRK2 | c.249del p.D84Tfs*7 | Frame Shift Del (DEL) | VAF 40/129 reads (31%) | catalogued as rs780517094; called by mutect2, pindel, varscan2
- WDR62 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 327/787 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs771467789, COSV99544294; called by muse, mutect2, varscan2
- XYLT2 | c.2120C>T p.T707M | Missense Mutation (SNP) | VAF 161/434 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs777713394; called by muse, mutect2, varscan2
- ZBTB38 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs752475828; called by muse, mutect2, varscan2
- ZNF184 | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1198525191; called by muse, mutect2, varscan2
- ZNF205 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 114/287 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375462960; called by muse, mutect2, varscan2
- ZNF280C | c.494-1G>T p.X165_splice | Splice Site (SNP) | VAF 5/92 reads (5%) | catalogued as COSV100921219; called by muse, mutect2
- ZNF492 | c.182dup p.N61Kfs*12 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs754633801; called by mutect2, varscan2
- ZNF608 | c.2534C>G p.A845G | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as COSV60435863; called by muse, mutect2, varscan2
- ZNF668 | c.1543del p.Q515Sfs*14 | Frame Shift Del (DEL) | VAF 18/140 reads (13%) | catalogued as rs760397907; called by mutect2, pindel, varscan2
- ZNF835 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 274/740 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV73379615; called by muse, mutect2, varscan2
- ABCC2 | c.633-2A>G p.X211_splice | Splice Site (SNP) | VAF 57/444 reads (13%) | called by muse, varscan2
- ABTB1 | c.692del p.P231Hfs*123 (on ENST00000232744 / NM_172027.3; = p.P89Hfs*123 on NM_032548.3) | Frame Shift Del (DEL) | VAF 56/157 reads (36%) | called by mutect2, pindel, varscan2
- AC013489.1 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACTN3 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2
- ADAM12 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 19/543 reads (3%) | called by muse, mutect2
- ADAM8 | c.705+6C>T | Splice Region (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- ADCY2 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AEBP2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 23/295 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2
- AIRE | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 52/579 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- AKR1A1 | c.779G>A p.C260Y | Missense Mutation (SNP) | VAF 179/466 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ALDH4A1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 69/556 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- AMPD2 | c.2044A>G p.S682G | Missense Mutation (SNP) | VAF 200/554 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKFN1 | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.469); called by muse, mutect2
- ANKRD11 | c.5206G>A p.V1736M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD50 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 119/384 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- AQP5 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- AQP7 | c.334T>A p.F112I | Missense Mutation (SNP) | VAF 133/348 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- ARAP2 | c.1208del p.N403Tfs*4 | Frame Shift Del (DEL) | VAF 58/179 reads (32%) | called by mutect2, pindel, varscan2
- AREL1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ARFGEF3 | c.2047C>A p.L683I | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP22 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 16/503 reads (3%) | called by muse, mutect2
- ARHGAP42 | c.2540A>G p.Y847C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, varscan2
- ARHGAP9 | c.207_208del p.P70Lfs*58 | Frame Shift Del (DEL) | VAF 178/542 reads (33%) | called by mutect2, pindel, varscan2
- ARHGEF15 | c.1408G>T p.G470* | Nonsense Mutation (SNP) | VAF 32/258 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.1042G>T p.V348F | Missense Mutation (SNP) | VAF 128/326 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARID1A | c.879del p.T294Pfs*69 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel
- ARID1A | c.4555dup p.Q1519Pfs*13 | Frame Shift Ins (INS) | VAF 80/281 reads (28%) | called by mutect2, pindel, varscan2
- ARL4D | c.597dup p.R200Efs*14 | Frame Shift Ins (INS) | VAF 47/127 reads (37%) | called by mutect2, pindel, varscan2
- ARRB2 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASIC4 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 144/355 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ASTN1 | c.1114A>G p.S372G | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- ATF7IP | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 11/115 reads (10%) | called by mutect2, pindel
- BAHCC1 | c.2502del p.H835Tfs*139 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.6781del p.D2261Tfs*191 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | called by mutect2, pindel, varscan2
- BCO1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- BCORL1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); called by muse, mutect2
- BCORL1 | c.3674C>T p.T1225M | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BICRA | c.3222del p.T1075Rfs*71 | Frame Shift Del (DEL) | VAF 84/261 reads (32%) | called by mutect2, pindel, varscan2
- BMS1 | c.2167A>G p.R723G | Missense Mutation (SNP) | VAF 137/331 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- BOC | c.704del p.P235Qfs*47 | Frame Shift Del (DEL) | VAF 80/215 reads (37%) | called by mutect2, pindel, varscan2
- BUB3 | c.241dup p.M81Nfs*3 | Frame Shift Ins (INS) | VAF 110/342 reads (32%) | called by mutect2, pindel, varscan2
- C11orf42 | c.73-2A>G p.X25_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- CA5B | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.253); called by muse, mutect2
- CACNA1C | c.4886G>A p.R1629Q | Missense Mutation (SNP) | VAF 99/273 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CACNA2D3 | c.2995G>A p.V999I | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CACNG8 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMSAP2 | c.4285G>T p.G1429C (on ENST00000236925 / NM_001297707.2; = p.G1418C on NM_203459.3) | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAND1 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CAPN6 | c.1499A>T p.D500V | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CCAR1 | c.2416del p.S806Afs*85 | Frame Shift Del (DEL) | VAF 60/213 reads (28%) | called by mutect2, pindel, varscan2
- CCDC87 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD8A | c.613del p.Y205Tfs*87 | Frame Shift Del (DEL) | VAF 208/596 reads (35%) | called by mutect2, pindel, varscan2
- CDS1 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- CENPF | c.7972_7973del p.K2658Efs*14 | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | called by mutect2, pindel, varscan2
- CEP85L | c.1523T>A p.I508N | Missense Mutation (SNP) | VAF 105/258 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFHR3 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 161/594 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CLEC16A | c.1832del p.L611Wfs*11 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- CMTR2 | c.1830del p.F610Lfs*34 | Frame Shift Del (DEL) | VAF 44/85 reads (52%) | called by mutect2, pindel, varscan2
- CNGA3 | c.1116del p.V373* | Frame Shift Del (DEL) | VAF 20/153 reads (13%) | called by mutect2, pindel, varscan2
- COL8A1 | c.1795del p.H599Mfs*24 | Frame Shift Del (DEL) | VAF 33/311 reads (11%) | called by mutect2, pindel, varscan2
- CPSF1 | c.3667C>A p.L1223M | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CREB3 | c.1085_1086del p.S362Cfs*49 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | called by pindel, varscan2
- CREBRF | c.1020del p.F340Lfs*75 | Frame Shift Del (DEL) | VAF 126/352 reads (36%) | called by mutect2, pindel, varscan2
- CRTAC1 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.061); called by muse, mutect2
- CSKMT | c.316del p.V106Wfs*11 | Frame Shift Del (DEL) | VAF 103/343 reads (30%) | called by mutect2, pindel, varscan2
- CTNND2 | c.861del p.E288Rfs*44 | Frame Shift Del (DEL) | VAF 61/202 reads (30%) | called by mutect2, pindel, varscan2
- CXCR1 | c.829T>C p.C277R | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND2B | c.2281A>G p.S761G | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DHCR24 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 79/206 reads (38%) | called by muse, mutect2, varscan2
- DLG2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DLGAP4 | c.604T>A p.S202T | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2
- DNAH1 | c.7037del p.P2346Rfs*12 | Frame Shift Del (DEL) | VAF 115/318 reads (36%) | called by mutect2, pindel, varscan2
- DNAI4 | c.2438_2440del p.D813del | In Frame Del (DEL) | VAF 16/175 reads (9%) | called by mutect2, pindel
- DPP9 | c.592C>A p.P198T (on ENST00000598800; = p.P227T on NM_139159.5) | Missense Mutation (SNP) | VAF 151/390 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- DSCAM | c.5860G>A p.A1954T | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DZIP3 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EBF2 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- EFHD1 | c.370del p.A124Pfs*8 | Frame Shift Del (DEL) | VAF 24/176 reads (14%) | called by mutect2, varscan2
- EMILIN3 | c.2282G>C p.R761P | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- ERCC2 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 132/344 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- F5 | c.6366G>A p.W2122* | Nonsense Mutation (SNP) | VAF 147/560 reads (26%) | called by muse, varscan2
- FAM120A | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- FAT4 | c.7190C>T p.A2397V | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FBRSL1 | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FER1L5 | c.2074C>A p.P692T (on ENST00000623019; = p.P697T on NM_001293083.2) | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHAD1 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 43/357 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- FIGNL2 | c.1322T>C p.L441P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FIGNL2 | c.495del p.Y166Tfs*66 | Frame Shift Del (DEL) | VAF 51/139 reads (37%) | called by mutect2, pindel, varscan2
- FKBP10 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 235/634 reads (37%) | called by muse, mutect2, varscan2
- FKRP | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2
- FLG | c.5725A>G p.R1909G | Missense Mutation (SNP) | VAF 116/970 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FMN2 | c.155del p.G52Efs*90 | Frame Shift Del (DEL) | VAF 54/182 reads (30%) | called by mutect2, varscan2
- FOLR2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.259); called by muse, mutect2
- FOXA2 | c.745_746del p.L249Afs*112 (on ENST00000377115 / NM_153675.3; = p.L255Afs*112 on NM_021784.5) | Frame Shift Del (DEL) | VAF 77/226 reads (34%) | called by mutect2, pindel, varscan2
- FOXG1 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 343/849 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FOXI3 | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 178/444 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- FOXJ1 | c.350A>T p.N117I | Missense Mutation (SNP) | VAF 127/350 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FRMD4A | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 187/470 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- FRMD7 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FUS | c.455del p.P152Lfs*33 | Frame Shift Del (DEL) | VAF 205/636 reads (32%) | called by mutect2, pindel, varscan2
- GABBR1 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.877); called by muse, mutect2
- GABRQ | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- GALNT5 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- GCSAML | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 138/504 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GGACT | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- GLUL | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 274/975 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1413G>T p.E471D | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.388); called by muse, mutect2
- GPRASP1 | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRIA2 | c.229T>C p.F77L | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.571); called by muse, varscan2
- GRID1 | c.1658G>A p.S553N | Missense Mutation (SNP) | VAF 50/424 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRP | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 128/313 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- H3-3B | c.85del p.S29Afs*8 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, pindel, varscan2
- HEATR5A | c.33A>C p.E11D | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECA | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HELLS | c.461dup p.N154Kfs*2 | Frame Shift Ins (INS) | VAF 30/92 reads (33%) | called by mutect2, varscan2
- HELLS | c.1864del p.S622Hfs*3 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.6683del p.G2228Vfs*5 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | called by mutect2, pindel
- HIVEP3 | c.1402C>T p.L468F | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- HSPBP1 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 173/506 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- IFTAP | c.554A>T p.N185I | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2
- IL6R | c.910A>G p.S304G | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- INSR | c.25del p.A9Rfs*56 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- INTS7 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ITGA6 | c.681dup p.D228* | Frame Shift Ins (INS) | VAF 122/336 reads (36%) | called by mutect2, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | called by mutect2, pindel, varscan2
- KCNB1 | c.1531T>C p.S511P | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNG1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNH2 | c.2791C>A p.P931T | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNK7 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- KIF24 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 124/299 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KIRREL1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2
- LAMA1 | c.8758T>C p.F2920L | Missense Mutation (SNP) | VAF 156/422 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LGALS3BP | c.1311del p.P438Lfs*86 | Frame Shift Del (DEL) | VAF 95/288 reads (33%) | called by mutect2, pindel, varscan2
- LPIN3 | c.2129del p.G710Afs*24 | Frame Shift Del (DEL) | VAF 61/186 reads (33%) | called by mutect2, pindel, varscan2
- LRP11 | c.511A>G p.N171D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LRP4 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 174/450 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- LRRC66 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 8/219 reads (4%) | called by muse, mutect2
- LRRC7 | c.3192del p.V1065Sfs*16 (on ENST00000651989 / NM_001370785.2; = p.V1032Sfs*16 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 127/382 reads (33%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.3118_3119del p.D1040* | Frame Shift Del (DEL) | VAF 34/316 reads (11%) | called by mutect2, pindel, varscan2
- MCTP1 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MED13L | c.5059T>C p.Y1687H | Missense Mutation (SNP) | VAF 28/585 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- MEGF11 | c.699del p.C234Vfs*53 | Frame Shift Del (DEL) | VAF 54/179 reads (30%) | called by mutect2, pindel, varscan2
- MRI1 | c.153A>G p.I51M | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MRPS18B | c.260del p.P87Hfs*34 | Frame Shift Del (DEL) | VAF 110/340 reads (32%) | called by mutect2, pindel, varscan2
- MSLN | c.1803G>A p.M601I (on ENST00000382862 / NM_013404.4; = p.M593I on NM_005823.6) | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTMR3 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- MUC16 | c.4738T>A p.S1580T | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- MUC19 | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC19 | c.371del p.K124Nfs*15 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- MYBPH | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MYO18A | c.1645A>G p.I549V | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2
- NACAD | c.4199G>A p.G1400D | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- NAV3 | c.3400_3401del p.Q1134Ifs*29 | Frame Shift Del (DEL) | VAF 106/320 reads (33%) | called by mutect2, pindel, varscan2
- NCR2 | c.531-5T>C | Splice Region (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- NEMF | c.867del p.F289Lfs*15 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- NEXN | c.964_966del p.R322del | In Frame Del (DEL) | VAF 96/296 reads (32%) | called by pindel, varscan2
- NLK | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP10 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 103/260 reads (40%) | called by muse, mutect2, varscan2
- NOTCH2 | c.5089del p.V1697* | Frame Shift Del (DEL) | VAF 91/712 reads (13%) | called by mutect2, pindel, varscan2
- NPAT | c.3630del p.K1210Nfs*14 | Frame Shift Del (DEL) | VAF 208/542 reads (38%) | called by mutect2, varscan2
- NPTN | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- NRXN2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- NSMF | c.196del p.Q66Rfs*59 | Frame Shift Del (DEL) | VAF 115/337 reads (34%) | called by mutect2, pindel, varscan2
- NUDT11 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 55/459 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2W3 | c.850dup p.L284Pfs*? | Frame Shift Ins (INS) | VAF 86/433 reads (20%) | called by mutect2, pindel, varscan2
- OR52B6 | c.445del p.L149Cfs*20 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | called by mutect2, pindel, varscan2
- OR8D4 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PACC1 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 161/560 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCF11 | c.2399del p.G800Efs*5 | Frame Shift Del (DEL) | VAF 89/265 reads (34%) | called by mutect2, pindel, varscan2
- PDE6B | c.1609dup p.Q537Pfs*62 | Frame Shift Ins (INS) | VAF 204/620 reads (33%) | called by mutect2, pindel, varscan2
- PDS5B | c.1662_1664del p.E554del | In Frame Del (DEL) | VAF 50/173 reads (29%) | called by pindel, varscan2
- PDZD2 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PDZD4 | c.1594del p.R532Gfs*23 | Frame Shift Del (DEL) | VAF 107/331 reads (32%) | called by mutect2, pindel, varscan2
- PHIP | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 15/358 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- PIK3C2B | c.3718A>G p.M1240V | Missense Mutation (SNP) | VAF 100/352 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PIK3R1 | c.1142_1144del p.I381del (on ENST00000521381 / NM_181523.3; = p.I111del on NM_181504.4) | In Frame Del (DEL) | VAF 44/127 reads (35%) | called by mutect2, pindel, varscan2
- PLCL2 | c.2507A>G p.Y836C (on ENST00000615277 / NM_001144382.2; = p.Y710C on NM_015184.5) | Missense Mutation (SNP) | VAF 214/596 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLK2 | c.1490T>C p.L497P | Missense Mutation (SNP) | VAF 234/575 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PNMA8A | c.180dup p.V61Cfs*7 | Frame Shift Ins (INS) | VAF 71/221 reads (32%) | called by mutect2, pindel, varscan2
- POLR3D | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PPIAL4D | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- PPP1R37 | c.1228T>C p.S410P | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PPP1R3D | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PPP4R1 | c.1786G>A p.D596N (on ENST00000400556 / NM_001042388.3; = p.D579N on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); called by muse, mutect2
- PRICKLE1 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PROX1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAI1 | c.2396dup p.G800Wfs*36 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | called by pindel, varscan2
- RALGAPA2 | c.3269G>A p.S1090N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP17 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- RANBP17 | c.3182dup p.N1061Kfs*16 | Frame Shift Ins (INS) | VAF 49/170 reads (29%) | called by mutect2, pindel, varscan2
- RAX | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 71/388 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- RBM47 | c.389A>G p.E130G | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.106); called by muse, mutect2
- RBMXL3 | c.2027dup p.L676Ffs*12 | Frame Shift Ins (INS) | VAF 178/672 reads (26%) | called by mutect2, pindel, varscan2
- RC3H1 | c.1961A>G p.Q654R | Missense Mutation (SNP) | VAF 25/470 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.3); called by muse, mutect2
- RFX7 | c.255dup p.A86Sfs*12 (on ENST00000559447 / NM_001368074.1; = p.A183Sfs*12 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 64/188 reads (34%) | called by mutect2, varscan2
- RGL1 | c.215G>A p.G72D (on ENST00000360851 / NM_001297672.2; = p.G107D on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS19 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- SATB2 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 203/549 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCGN | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 64/154 reads (42%) | called by muse, mutect2, varscan2
- SDR42E2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SEC31A | c.1820A>C p.Q607P (on ENST00000355196 / NM_001318120.1; = p.Q568P on NM_016211.4) | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SELENOF | c.194A>G p.Q65R | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEPTIN3 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- SH2B1 | c.1715G>A p.G572D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH2B1 | c.1817T>C p.V606A | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SHANK1 | c.2783dup p.P929Tfs*43 | Frame Shift Ins (INS) | VAF 63/196 reads (32%) | called by mutect2, pindel, varscan2
- SIX2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- SKI | c.1015A>T p.T339S | Missense Mutation (SNP) | VAF 198/476 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC11A2 | c.720del p.F240Lfs*19 (on ENST00000394904 / NM_001379455.1; = p.F211Lfs*19 on NM_000617.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 135/406 reads (33%) | called by mutect2, varscan2
- SLC13A5 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- SLC23A2 | c.1836del p.K612Nfs*64 | Frame Shift Del (DEL) | VAF 120/332 reads (36%) | called by mutect2, pindel, varscan2
- SLC2A3 | c.510+1G>A p.X170_splice | Splice Site (SNP) | VAF 100/236 reads (42%) | called by muse, mutect2
- SLC44A5 | c.1414A>G p.I472V | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.14); called by muse, mutect2
- SLC4A9 | c.2810T>C p.L937P (on ENST00000507527 / NM_001258428.2; = p.L913P on NM_031467.3) | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A3 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 189/841 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- SMOC2 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SNX9 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPECC1 | c.3156G>A p.W1052* | Nonsense Mutation (SNP) | VAF 155/438 reads (35%) | called by muse, mutect2, varscan2
- SPEG | c.1879_1880insA p.P627Hfs*39 | Frame Shift Ins (INS) | VAF 20/134 reads (15%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SRRM2 | c.2357C>A p.P786H | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- STK19 | c.1013G>A p.G338D (on ENST00000375333 / NM_032454.1; = p.G334D on NM_004197.1) | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYNE3 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TBC1D1 | c.2712G>T p.M904I | Missense Mutation (SNP) | VAF 151/433 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TCERG1L | c.1691dup p.N565Qfs*8 | Frame Shift Ins (INS) | VAF 54/173 reads (31%) | called by mutect2, pindel, varscan2
- TECR | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 103/277 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- TENM3 | c.1412A>G p.Q471R | Missense Mutation (SNP) | VAF 57/393 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX11 | c.646dup p.Q216Pfs*21 (on ENST00000344304; = p.Q201Pfs*21 on NM_031276.3) | Frame Shift Ins (INS) | VAF 21/166 reads (13%) | called by mutect2, pindel, varscan2
- TEX15 | c.6509dup p.L2171Afs*14 (on ENST00000256246; = p.L2554Afs*14 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 49/146 reads (34%) | called by mutect2, pindel, varscan2
- TFCP2L1 | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TFR2 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 168/430 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TKTL1 | c.343A>G p.R115G | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2
- TM6SF1 | c.342G>T p.W114C | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMED10 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFAIP3 | c.912del p.E305Sfs*3 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- TNRC18 | c.911del p.G304Vfs*286 | Frame Shift Del (DEL) | VAF 72/187 reads (39%) | called by mutect2, pindel, varscan2
- TNRC6B | c.2251del p.E751Rfs*41 | Frame Shift Del (DEL) | VAF 37/110 reads (34%) | called by mutect2, pindel, varscan2
- TNS3 | c.4028C>T p.P1343L | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.817); called by muse, mutect2
- TRAM1L1 | c.1033del p.R345Efs*14 | Frame Shift Del (DEL) | VAF 58/173 reads (34%) | called by mutect2, pindel, varscan2
- TRPM5 | c.1621G>T p.G541C | Missense Mutation (SNP) | VAF 119/348 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- TSKU | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 109/293 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSPOAP1 | c.2042C>T p.T681I | Missense Mutation (SNP) | VAF 117/334 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- TSPOAP1 | c.439C>T p.L147= | Splice Region (SNP) | VAF 63/166 reads (38%) | called by muse, mutect2, varscan2
- TTC39B | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC9B | c.301del p.A101Pfs*51 | Frame Shift Del (DEL) | VAF 18/173 reads (10%) | called by mutect2, pindel
- TTLL11 | c.2348del p.P783Hfs*87 | Frame Shift Del (DEL) | VAF 41/123 reads (33%) | called by mutect2, pindel, varscan2
- TUBA1A | c.44A>C p.Q15P | Missense Mutation (SNP) | VAF 52/590 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- U2SURP | c.1572del p.F524Lfs*2 | Frame Shift Del (DEL) | VAF 22/246 reads (9%) | called by mutect2, pindel
- UBR5 | c.3844_3847del p.T1282Sfs*37 | Frame Shift Del (DEL) | VAF 76/270 reads (28%) | called by pindel, varscan2
- USP40 | c.2538dup p.A847Cfs*5 | Frame Shift Ins (INS) | VAF 81/228 reads (36%) | called by mutect2, pindel, varscan2
- USP9X | c.544T>A p.C182S | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VILL | c.266del p.G89Afs*32 | Frame Shift Del (DEL) | VAF 190/562 reads (34%) | called by mutect2, pindel, varscan2
- VPS13B | c.173del p.L58* | Frame Shift Del (DEL) | VAF 56/193 reads (29%) | called by mutect2, pindel, varscan2
- WDCP | c.563A>G p.Q188R | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDFY1 | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR46 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 134/330 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- WIZ | c.2145_2146insA p.P716Tfs*73 | Frame Shift Ins (INS) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- WNT5B | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 148/354 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZC3H12B | c.1045_1048del p.K349Dfs*52 | Frame Shift Del (DEL) | VAF 62/184 reads (34%) | called by pindel, varscan2
- ZCCHC18 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 49/466 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ZDHHC18 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC8 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZFHX2 | c.1199dup p.T401Hfs*14 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- ZFYVE28 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2
- ZNF140 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ZNF175 | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 118/316 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF205 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF268 | c.1268_1289del p.K423Tfs*40 | Frame Shift Del (DEL) | VAF 80/223 reads (36%) | called by mutect2, pindel*
- ZNF300 | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.205); called by muse, mutect2
- ZNF491 | c.1112A>G p.H371R | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF579 | c.1310dup p.A439Sfs*70 | Frame Shift Ins (INS) | VAF 42/124 reads (34%) | called by mutect2, pindel, varscan2
- ZNF707 | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ZNF845 | c.2865del p.A956Qfs*49 | Frame Shift Del (DEL) | VAF 49/166 reads (30%) | called by mutect2, pindel, varscan2
- ZNF850 | c.2167C>A p.H723N | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ABCC1 | c.2508C>T p.D836= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as rs374092475; called by muse, mutect2, varscan2
- ABCF1 | c.2205C>A p.A735= (on ENST00000326195 / NM_001025091.2; = p.A697= on NM_001090.3) | Silent (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- ABHD12 | c.375G>A p.T125= | Silent (SNP) | VAF 17/548 reads (3%) | catalogued as rs1048930924; called by muse, mutect2
- ACHE | c.669T>C p.G223= | Silent (SNP) | VAF 167/502 reads (33%) | called by muse, mutect2, varscan2
- ACSL6 | c.628C>T p.L210= (on ENST00000379240; = p.L235= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/163 reads (40%) | called by muse, mutect2, varscan2
- ADCY10 | c.3891C>T p.Y1297= | Silent (SNP) | VAF 300/1124 reads (27%) | catalogued as rs777383170, COSV63238873, COSV63241431; called by muse, mutect2, varscan2
- ADRA1D | c.1374C>T p.P458= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs1008039802; called by muse, mutect2
- AIMP2 | c.834C>T p.D278= | Silent (SNP) | VAF 46/371 reads (12%) | catalogued as rs762745274; called by muse, mutect2, varscan2
- AKR1E2 | c.261T>C p.S87= | Silent (SNP) | VAF 70/217 reads (32%) | catalogued as COSV53631034; called by muse, mutect2, varscan2
- AL645922.1 | c.1363C>T p.L455= | Silent (SNP) | VAF 60/596 reads (10%) | catalogued as rs754558727; called by muse, mutect2, varscan2
- ALG3 | c.954G>A p.S318= | Silent (SNP) | VAF 121/344 reads (35%) | catalogued as rs372494174; ClinVar: benign; called by muse, mutect2, varscan2
- ALK | c.1752C>T p.V584= | Silent (SNP) | VAF 132/315 reads (42%) | catalogued as rs367912697, COSV66571484; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMDHD1 | c.109C>T p.L37= | Silent (SNP) | VAF 85/193 reads (44%) | called by muse, mutect2, varscan2
- ANKRD11 | c.2889C>T p.D963= | Silent (SNP) | VAF 185/257 reads (72%) | catalogued as rs139955323; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANTXRL | c.504C>T p.S168= | Silent (SNP) | VAF 106/285 reads (37%) | catalogued as rs1192984458; called by muse, mutect2, varscan2
- AP5B1 | c.1155T>C p.G385= | Silent (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- APBA2 | c.2136C>A p.A712= | Silent (SNP) | VAF 72/673 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF16 | c.744C>T p.D248= | Silent (SNP) | VAF 17/235 reads (7%) | catalogued as rs376771674; called by muse, mutect2
- ARHGEF33 | c.192C>A p.S64= | Silent (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- ATP12A | c.2310C>T p.F770= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as rs148902783; called by muse, mutect2, varscan2
- BAZ2B | c.2640C>T p.N880= | Silent (SNP) | VAF 44/318 reads (14%) | catalogued as rs761523929; called by muse, mutect2, varscan2
- BRD3 | c.483G>A p.A161= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs202180006, COSV57705528; called by muse, mutect2, varscan2
- CAMSAP3 | c.2790G>A p.Q930= | Silent (SNP) | VAF 63/219 reads (29%) | catalogued as rs1338783070; called by muse, mutect2, varscan2
- CARD11 | c.2562C>T p.S854= | Silent (SNP) | VAF 14/328 reads (4%) | called by muse, mutect2
- CASKIN1 | c.3768C>T p.G1256= | Silent (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- CCER1 | c.855T>C p.D285= | Silent (SNP) | VAF 64/139 reads (46%) | called by muse, mutect2, varscan2
- CEL | c.2010C>T p.A670= (on ENST00000673714; = p.A667= on NM_001807.6) | Silent (SNP) | VAF 47/68 reads (69%) | called by muse, varscan2
- CELSR2 | c.3336G>A p.Q1112= | Silent (SNP) | VAF 56/122 reads (46%) | called by muse, varscan2
- CELSR3 | c.2485C>T p.L829= | Silent (SNP) | VAF 153/482 reads (32%) | called by muse, mutect2, varscan2
- CEP41 | c.93C>T p.D31= | Silent (SNP) | VAF 35/288 reads (12%) | called by muse, mutect2, varscan2
- CHAT | c.1275C>A p.S425= | Silent (SNP) | VAF 124/335 reads (37%) | catalogued as rs767778694, COSV100340199; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHPF | c.1317G>A p.P439= | Silent (SNP) | VAF 153/359 reads (43%) | catalogued as rs1426234114, COSV60534735; called by muse, mutect2, varscan2
- CHST1 | c.969G>A p.P323= | Silent (SNP) | VAF 138/390 reads (35%) | catalogued as rs200393163, COSV57323820; called by muse, mutect2, varscan2
- CHST5 | c.726C>T p.R242= | Silent (SNP) | VAF 193/284 reads (68%) | catalogued as rs369009754; called by muse, mutect2, varscan2
- CNKSR3 | c.1194C>A p.T398= | Silent (SNP) | VAF 78/212 reads (37%) | called by muse, mutect2, varscan2
- COL2A1 | c.723C>A p.P241= | Silent (SNP) | VAF 97/251 reads (39%) | called by muse, mutect2, varscan2
- COL5A1 | c.3429G>A p.P1143= | Silent (SNP) | VAF 136/399 reads (34%) | catalogued as rs750169623, COSV100880774; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.4560C>T p.L1520= | Silent (SNP) | VAF 184/454 reads (41%) | catalogued as rs375279488; called by muse, mutect2, varscan2
- COL8A1 | c.1002G>A p.G334= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV53737805; called by muse, mutect2, varscan2
- CTNNB1 | c.777C>A p.L259= | Silent (SNP) | VAF 88/531 reads (17%) | catalogued as COSV62717108; called by muse, mutect2, varscan2
- CYP26A1 | c.1368A>G p.T456= | Silent (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- CYTH1 | c.1032C>T p.D344= | Silent (SNP) | VAF 35/221 reads (16%) | catalogued as rs199612995, COSV63122864; called by muse, mutect2, varscan2
- DACH1 | c.717G>A p.T239= | Silent (SNP) | VAF 28/372 reads (8%) | catalogued as rs754568859; called by muse, mutect2
- DGKH | c.747G>A p.Q249= | Silent (SNP) | VAF 22/332 reads (7%) | called by muse, mutect2
- DHX57 | c.3913C>T p.L1305= | Silent (SNP) | VAF 128/340 reads (38%) | called by muse, mutect2, varscan2
- DIPK2B | c.639G>A p.T213= | Silent (SNP) | VAF 60/133 reads (45%) | catalogued as rs747780326; called by muse, mutect2, varscan2
- DMGDH | c.216G>T p.G72= | Silent (SNP) | VAF 177/416 reads (43%) | catalogued as COSV54862251; called by muse, mutect2, varscan2
- DNASE2 | c.504G>A p.S168= | Silent (SNP) | VAF 255/670 reads (38%) | catalogued as rs140738663; called by muse, mutect2, varscan2
- DSP | c.6183C>A p.P2061= | Silent (SNP) | VAF 153/363 reads (42%) | called by muse, mutect2, varscan2
- ENO4 | c.147C>G p.A49= | Silent (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- ENOPH1 | c.594C>T p.D198= | Silent (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- EPHA3 | c.213C>T p.C71= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as COSV60703021; called by muse, mutect2, varscan2
- ERF | c.1065C>T p.P355= | Silent (SNP) | VAF 78/212 reads (37%) | catalogued as rs769453776; called by muse, mutect2, varscan2
- FAM43A | c.54G>A p.R18= | Silent (SNP) | VAF 96/251 reads (38%) | called by muse, mutect2, varscan2
- FAM43A | c.1002G>C p.P334= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV61673076; called by muse, mutect2, varscan2
- FAM47B | c.633C>T p.R211= | Silent (SNP) | VAF 32/480 reads (7%) | called by muse, mutect2
- FAM47C | c.1086C>T p.R362= | Silent (SNP) | VAF 18/462 reads (4%) | catalogued as rs781943797; called by muse, mutect2
- FAT2 | c.7503T>C p.I2501= | Silent (SNP) | VAF 33/238 reads (14%) | called by muse, mutect2, varscan2
- FAT2 | c.5172G>A p.S1724= | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as rs763383764, COSV55831807; called by muse, mutect2
- FBN1 | c.183A>G p.S61= | Silent (SNP) | VAF 38/586 reads (6%) | called by muse, mutect2
- FGB | c.381T>C p.V127= | Silent (SNP) | VAF 119/291 reads (41%) | called by muse, mutect2, varscan2
- FGF3 | c.714G>A p.A238= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as rs564356317; called by muse, mutect2
- FIBIN | c.514C>T p.L172= | Silent (SNP) | VAF 87/226 reads (38%) | called by muse, mutect2, varscan2
- FIG4 | c.1518C>A p.A506= | Silent (SNP) | VAF 32/442 reads (7%) | catalogued as COSV57787382; called by muse, mutect2
- FNDC8 | c.408G>A p.A136= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs764202427, COSV99338870, COSV99339096; called by muse, mutect2, varscan2
- FOXI2 | c.393C>T p.Y131= | Silent (SNP) | VAF 149/441 reads (34%) | catalogued as rs761072331; called by muse, mutect2, varscan2
- FOXP2 | c.999T>C p.H333= | Silent (SNP) | VAF 159/445 reads (36%) | called by muse, mutect2, varscan2
- FSTL4 | c.972C>T p.S324= | Silent (SNP) | VAF 108/309 reads (35%) | catalogued as rs190908572; called by muse, mutect2, varscan2
- FZD8 | c.1962C>T p.G654= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
- GATA5 | c.615C>A p.T205= | Silent (SNP) | VAF 182/522 reads (35%) | catalogued as COSV99435657; called by muse, mutect2
- GET3 | c.958C>T p.L320= | Silent (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- GLP1R | c.843T>C p.V281= | Silent (SNP) | VAF 79/215 reads (37%) | called by muse, mutect2, varscan2
- GP6 | c.525C>T p.S175= | Silent (SNP) | VAF 105/239 reads (44%) | catalogued as rs367907292; called by muse, mutect2, varscan2
- GPR6 | c.765C>T p.H255= | Silent (SNP) | VAF 57/388 reads (15%) | catalogued as rs367576936; called by muse, mutect2, varscan2
- GRHL3 | c.525C>T p.S175= (on ENST00000350501 / NM_198174.3; = p.S180= on NM_021180.3) | Silent (SNP) | VAF 74/171 reads (43%) | called by muse, mutect2, varscan2
- GSN | c.1873C>T p.L625= | Silent (SNP) | VAF 89/225 reads (40%) | called by muse, mutect2, varscan2
- H6PD | c.2361C>T p.D787= | Silent (SNP) | VAF 210/674 reads (31%) | catalogued as rs766210010; called by muse, mutect2, varscan2
- HECTD4 | c.10623C>T p.T3541= | Silent (SNP) | VAF 159/410 reads (39%) | catalogued as rs1360333455, COSV101108436; called by muse, mutect2, varscan2
- HMGB2 | c.117G>T p.A39= | Silent (SNP) | VAF 53/153 reads (35%) | called by muse, mutect2, varscan2
- HTR1E | c.621C>T p.H207= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as rs377350581; called by muse, mutect2, varscan2
- KANK1 | c.2301C>T p.N767= | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as rs745379692; called by muse, mutect2, varscan2
- KCNC1 | c.249C>T p.C83= | Silent (SNP) | VAF 184/473 reads (39%) | catalogued as COSV56391450; called by muse, mutect2, varscan2
- KCTD15 | c.612C>T p.S204= | Silent (SNP) | VAF 32/300 reads (11%) | catalogued as rs937645040; called by muse, mutect2, varscan2
- KIAA1671 | c.3099G>A p.Q1033= | Silent (SNP) | VAF 165/465 reads (35%) | called by muse, mutect2, varscan2
- KLHDC8B | c.336C>A p.T112= | Silent (SNP) | VAF 15/175 reads (9%) | called by muse, mutect2
- KNG1 | c.87T>C p.N29= | Silent (SNP) | VAF 45/331 reads (14%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.699C>T p.Y233= | Silent (SNP) | VAF 66/175 reads (38%) | catalogued as rs375609451; called by muse, mutect2
- LCE1E | c.315C>T p.C105= | Silent (SNP) | VAF 24/202 reads (12%) | called by muse, varscan2
- LINGO4 | c.1002C>T p.N334= | Silent (SNP) | VAF 171/612 reads (28%) | catalogued as rs759877731; called by muse, mutect2, varscan2
- LRP3 | c.1476C>A p.A492= | Silent (SNP) | VAF 68/159 reads (43%) | called by muse, mutect2, varscan2
- LRRC7 | c.3546C>T p.G1182= (on ENST00000651989 / NM_001370785.2; = p.G1149= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 135/349 reads (39%) | catalogued as rs1207416827, COSV50416573; called by muse, mutect2, varscan2
- MAB21L2 | c.483C>T p.R161= | Silent (SNP) | VAF 26/213 reads (12%) | catalogued as COSV58262264; called by muse, mutect2, varscan2
- MAMDC4 | c.3096C>A p.P1032= (on ENST00000445819; = p.P953= on NM_206920.3) | Silent (SNP) | VAF 120/294 reads (41%) | catalogued as COSV56377405, COSV99807921; called by muse, mutect2, varscan2
- MAPKAPK2 | c.372C>T p.Y124= | Silent (SNP) | VAF 63/265 reads (24%) | catalogued as rs782726803, COSV54314372; called by muse, mutect2, varscan2
- MCF2L | c.3369C>T p.C1123= (on ENST00000375608; = p.C1091= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 178/485 reads (37%) | catalogued as rs777436276; called by muse, mutect2, varscan2
- MDC1 | c.5616G>A p.E1872= | Silent (SNP) | VAF 116/282 reads (41%) | called by muse, mutect2, varscan2
- MEFV | c.1983C>T p.D661= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- MIA3 | c.3432C>T p.N1144= | Silent (SNP) | VAF 71/262 reads (27%) | catalogued as rs374212330; called by muse, mutect2, varscan2
- MPPED2 | c.81G>A p.T27= | Silent (SNP) | VAF 13/259 reads (5%) | catalogued as rs1214837822, COSV63898154; called by muse, mutect2
- MRC2 | c.1476C>T p.N492= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as rs1246706869, COSV100316964; called by muse, mutect2, varscan2
- MRC2 | c.3018G>A p.Q1006= | Silent (SNP) | VAF 96/259 reads (37%) | catalogued as COSV57639169; called by muse, mutect2, varscan2
- MTHFD1 | c.390C>T p.I130= | Silent (SNP) | VAF 32/499 reads (6%) | called by muse, mutect2
- MTHFD1L | c.1404G>A p.A468= | Silent (SNP) | VAF 104/275 reads (38%) | catalogued as rs541518987; called by muse, mutect2, varscan2
- MYH14 | c.168G>A p.V56= | Silent (SNP) | VAF 23/311 reads (7%) | called by muse, mutect2
- MYO18B | c.6891C>T p.D2297= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs374327917; called by muse, mutect2, varscan2
- MYO5C | c.4623C>T p.D1541= | Silent (SNP) | VAF 178/446 reads (40%) | catalogued as rs997854517; called by muse, mutect2, varscan2
- NBEAL2 | c.8043G>A p.A2681= | Silent (SNP) | VAF 160/418 reads (38%) | catalogued as COSV52758012; called by muse, mutect2, varscan2
- NELL1 | c.96C>T p.I32= | Silent (SNP) | VAF 79/176 reads (45%) | catalogued as rs146112225, COSV54254024; called by muse, mutect2, varscan2
- NKX1-1 | c.1200C>T p.H400= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs1156946312; called by muse, mutect2, varscan2
- NLGN2 | c.633G>A p.T211= | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as rs1020500899; called by muse, mutect2
- NOTCH2 | c.3480C>T p.H1160= | Silent (SNP) | VAF 16/382 reads (4%) | catalogued as rs781935782; called by muse, mutect2
- NUDT11 | c.342G>A p.G114= | Silent (SNP) | VAF 56/459 reads (12%) | called by muse, mutect2, varscan2
- OCLN | c.624T>C p.Y208= | Silent (SNP) | VAF 70/474 reads (15%) | called by muse, mutect2, varscan2
- OR2G3 | c.216C>T p.C72= | Silent (SNP) | VAF 82/277 reads (30%) | catalogued as rs1405039614; called by muse, mutect2, varscan2
- PADI2 | c.1003C>T p.L335= | Silent (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- PCDHA11 | c.2118G>A p.V706= | Silent (SNP) | VAF 200/479 reads (42%) | called by muse, mutect2, varscan2
- PCK2 | c.1755C>T p.S585= | Silent (SNP) | VAF 223/523 reads (43%) | catalogued as rs753224801; called by muse, mutect2, varscan2
- PCSK7 | c.1083T>G p.P361= | Silent (SNP) | VAF 49/329 reads (15%) | called by muse, mutect2, varscan2
- PEX5 | c.1917G>A p.Q639= (on ENST00000420616; = p.Q631= on NM_000319.5) | Silent (SNP) | VAF 186/526 reads (35%) | catalogued as rs1271426444, COSV56958802; called by muse, mutect2, varscan2
- PFKFB1 | c.1342C>A p.R448= | Silent (SNP) | VAF 77/237 reads (32%) | catalogued as COSV51498327; called by muse, mutect2, varscan2
- PGBD4 | c.690C>T p.F230= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs1195096104, COSV99854661; called by muse, mutect2, varscan2
- PGM3 | c.69C>T p.Y23= | Silent (SNP) | VAF 84/320 reads (26%) | catalogued as rs202123065, COSV52286051; called by muse, mutect2, varscan2
- PIGS | c.1311A>G p.T437= | Silent (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- PINK1 | c.1138C>T p.L380= | Silent (SNP) | VAF 30/664 reads (5%) | called by muse, mutect2
- PLD4 | c.1038G>A p.T346= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV101190513; called by muse, mutect2, varscan2
- PLEKHG4 | c.3288G>A p.S1096= | Silent (SNP) | VAF 278/404 reads (69%) | catalogued as rs759284532, COSV58575242; called by muse, mutect2, varscan2
- PLOD1 | c.729C>T p.N243= | Silent (SNP) | VAF 107/253 reads (42%) | catalogued as rs567164584, COSV52140360; called by muse, mutect2, varscan2
- PLXNB1 | c.573G>A p.P191= | Silent (SNP) | VAF 84/189 reads (44%) | catalogued as rs374562347; called by muse, mutect2, varscan2
- POLR1D | c.151C>T p.L51= | Silent (SNP) | VAF 98/319 reads (31%) | catalogued as rs895912704; called by muse, mutect2, varscan2
- POM121 | c.3450C>T p.N1150= (on ENST00000434423; = p.N885= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/556 reads (3%) | catalogued as rs782388533; called by muse, mutect2
- PPCDC | c.165A>G p.R55= | Silent (SNP) | VAF 70/215 reads (33%) | called by muse, mutect2, varscan2
- PRG4 | c.822G>A p.T274= | Silent (SNP) | VAF 37/864 reads (4%) | catalogued as rs753262769, COSV66623637; called by muse, mutect2
- PRKACG | c.15C>T p.P5= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV55258301; called by muse, mutect2, varscan2
- PRPS2 | c.765A>G p.G255= | Silent (SNP) | VAF 66/240 reads (28%) | catalogued as COSV101037681; called by muse, mutect2, varscan2
- PRSS23 | c.948C>T p.S316= | Silent (SNP) | VAF 47/270 reads (17%) | catalogued as rs560539694, COSV54706723; called by muse, mutect2, varscan2
- PTPRC | c.390C>T p.S130= | Silent (SNP) | VAF 210/786 reads (27%) | catalogued as rs895114528, COSV100722981; called by muse, mutect2, varscan2
- PTPRN2 | c.2145C>T p.S715= | Silent (SNP) | VAF 27/213 reads (13%) | catalogued as rs747100294, COSV67049878; called by muse, mutect2, varscan2
- RADIL | c.2685G>A p.P895= | Silent (SNP) | VAF 141/337 reads (42%) | catalogued as rs374955459; called by muse, mutect2, varscan2
- RALA | c.108C>T p.Y36= | Silent (SNP) | VAF 84/194 reads (43%) | catalogued as rs1164540457; called by muse, mutect2, varscan2
- RBBP9 | c.186G>A p.E62= | Silent (SNP) | VAF 116/288 reads (40%) | called by muse, mutect2, varscan2
- RELN | c.6240C>T p.Y2080= | Silent (SNP) | VAF 254/715 reads (36%) | catalogued as rs201505136, COSV59018073; ClinVar: likely benign; called by muse, mutect2, varscan2
- RELN | c.732A>G p.E244= | Silent (SNP) | VAF 172/451 reads (38%) | called by muse, mutect2, varscan2
- RFPL2 | c.909A>G p.L303= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- RIPK4 | c.1218T>C p.S406= (on ENST00000352483; = p.S358= on NM_020639.3) | Silent (SNP) | VAF 36/369 reads (10%) | called by muse, mutect2
- RTL1 | c.4068C>T p.N1356= | Silent (SNP) | VAF 11/316 reads (3%) | called by muse, mutect2
- SEBOX | c.240A>G p.S80= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- SEMA6C | c.1200G>A p.P400= | Silent (SNP) | VAF 118/420 reads (28%) | catalogued as rs766427892; called by muse, mutect2, varscan2
- SERTAD4 | c.666C>T p.A222= | Silent (SNP) | VAF 118/361 reads (33%) | called by muse, mutect2, varscan2
- SFMBT2 | c.1719C>T p.N573= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as rs768766997, COSV62814378; called by muse, varscan2
- SIGLEC16 | c.59G>A p.*20= | Silent (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- SLC22A8 | c.348C>T p.C116= | Silent (SNP) | VAF 56/174 reads (32%) | called by muse, mutect2, varscan2
- SLC26A11 | c.909G>A p.V303= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs764693611; called by muse, mutect2, varscan2
- SORBS3 | c.27C>T p.R9= | Silent (SNP) | VAF 90/213 reads (42%) | catalogued as rs779309968, COSV53552706; called by muse, mutect2, varscan2
- SORCS1 | c.99C>T p.G33= | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- SORCS2 | c.3429C>T p.G1143= | Silent (SNP) | VAF 20/229 reads (9%) | catalogued as rs925423936; called by muse, mutect2
- SOX13 | c.1221C>T p.C407= | Silent (SNP) | VAF 108/413 reads (26%) | catalogued as rs376154453; called by muse, mutect2, varscan2
- SPARC | c.186C>T p.T62= | Silent (SNP) | VAF 26/289 reads (9%) | catalogued as rs769034890, COSV50561329; ClinVar: likely benign; called by muse, mutect2
- SPATA24 | c.471G>A p.Q157= | Silent (SNP) | VAF 87/219 reads (40%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.2073G>A p.V691= | Silent (SNP) | VAF 15/292 reads (5%) | called by muse, mutect2
- SPEG | c.4230C>T p.T1410= | Silent (SNP) | VAF 21/305 reads (7%) | catalogued as rs780757296, COSV100405892; called by muse, mutect2
- ST6GAL2 | c.1443G>A p.A481= | Silent (SNP) | VAF 28/502 reads (6%) | catalogued as rs367555800, COSV62417302; called by muse, mutect2
- ST6GALNAC6 | c.303G>A p.L101= | Silent (SNP) | VAF 10/169 reads (6%) | called by muse, mutect2
- TCF3 | c.1125C>T p.P375= | Silent (SNP) | VAF 102/268 reads (38%) | catalogued as rs767996769; called by muse, mutect2, varscan2
- TEP1 | c.6639C>T p.T2213= | Silent (SNP) | VAF 10/268 reads (4%) | catalogued as rs949659669; called by muse, mutect2
- TJP1 | c.1935G>A p.R645= | Silent (SNP) | VAF 63/203 reads (31%) | called by muse, mutect2, varscan2
- TMC2 | c.150C>T p.R50= | Silent (SNP) | VAF 230/621 reads (37%) | catalogued as rs1473354870; called by muse, mutect2, varscan2
- TMEM143 | c.828G>A p.L276= | Silent (SNP) | VAF 176/407 reads (43%) | called by muse, mutect2, varscan2
- TNR | c.2361C>T p.S787= | Silent (SNP) | VAF 33/153 reads (22%) | called by muse, varscan2
- TONSL | c.1518G>A p.E506= | Silent (SNP) | VAF 186/467 reads (40%) | catalogued as rs905673833; called by muse, mutect2, varscan2
- TONSL | c.117C>T p.G39= | Silent (SNP) | VAF 94/229 reads (41%) | called by muse, mutect2, varscan2
- TP53BP2 | c.1662G>A p.G554= (on ENST00000343537 / NM_001031685.3; = p.G425= on NM_005426.2) | Silent (SNP) | VAF 31/283 reads (11%) | called by muse, mutect2, varscan2
- TRDN | c.177G>A p.T59= | Silent (SNP) | VAF 98/290 reads (34%) | catalogued as rs765305855; called by muse, mutect2, varscan2
- TUB | c.525G>A p.R175= (on ENST00000299506 / NM_177972.3; = p.R230= on NM_003320.4) | Silent (SNP) | VAF 13/255 reads (5%) | called by muse, mutect2
- UNC5D | c.231G>A p.A77= | Silent (SNP) | VAF 120/300 reads (40%) | catalogued as rs1335791003, COSV54768776; called by muse, mutect2, varscan2
- WDR87 | c.2739G>A p.Q913= | Silent (SNP) | VAF 95/238 reads (40%) | catalogued as COSV58205323; called by muse, mutect2, varscan2
- WWC2 | c.780C>T p.G260= | Silent (SNP) | VAF 35/131 reads (27%) | called by muse, mutect2, varscan2
- YARS2 | c.1296C>T p.G432= | Silent (SNP) | VAF 105/319 reads (33%) | catalogued as rs762688909; called by muse, mutect2, varscan2
- ZBTB20 | c.1350C>T p.N450= (on ENST00000474710 / NM_001164342.2; = p.N377= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 210/545 reads (39%) | called by muse, mutect2, varscan2
- ZMYND10 | c.228C>T p.I76= | Silent (SNP) | VAF 22/268 reads (8%) | catalogued as rs764843322; called by muse, mutect2
- ZNF214 | c.1422A>G p.E474= | Silent (SNP) | VAF 51/136 reads (38%) | called by muse, mutect2, varscan2
- ZNF286A | c.165A>G p.T55= | Silent (SNP) | VAF 70/209 reads (33%) | called by muse, mutect2, varscan2
- ZNF512B | c.228G>A p.R76= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99411766; called by muse, mutect2, varscan2
- ZNF516 | c.489C>T p.S163= | Silent (SNP) | VAF 23/357 reads (6%) | catalogued as rs780237445; called by muse, mutect2
- ZNF697 | c.699G>A p.A233= | Silent (SNP) | VAF 78/188 reads (41%) | catalogued as rs1432665136; called by muse, mutect2, varscan2
- ZNF835 | c.849C>T p.C283= | Silent (SNP) | VAF 35/692 reads (5%) | catalogued as rs1200120422; called by muse, mutect2
- ZNHIT2 | c.363G>A p.R121= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.15G>A p.A5= (on ENST00000252463; = p.A60= on NM_032805.3) | Silent (SNP) | VAF 69/179 reads (39%) | catalogued as rs377042269; called by muse, mutect2, varscan2
- ABCA13 | c.12070+51G>A | Intron (SNP) | VAF 74/181 reads (41%) | called by muse, mutect2, varscan2
- ABCA4 | c.-36A>G | 5'UTR (SNP) | VAF 170/453 reads (38%) | called by muse, mutect2, varscan2
- ACSL5 | c.-74G>T | 5'UTR (SNP) | VAF 96/274 reads (35%) | called by muse, mutect2, varscan2
- ADAM11 | c.*27G>A | 3'UTR (SNP) | VAF 18/195 reads (9%) | catalogued as COSV99567014; called by muse, mutect2
- ADCY10P1 | n.3638-590dup | Intron (INS) | VAF 53/173 reads (31%) | called by mutect2, pindel, varscan2
- AGPAT3 | c.*2726G>T | 3'UTR (SNP) | VAF 189/501 reads (38%) | called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516679 C>T | 3'Flank (SNP) | VAF 118/349 reads (34%) | catalogued as rs1285961758; called by muse, mutect2, varscan2
- ALS2 | c.3702+26_3702+50delinsCTCCCTAATAAATTCTTTTACTAAT | Intron (ONP) | VAF 28/188 reads (15%) | called by mutect2*, pindel, varscan2*
- AP001830.2 | n.285del | RNA (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- AP002008.2 | n.1973G>T | RNA (SNP) | VAF 93/237 reads (39%) | called by muse, mutect2, varscan2
- BHLHE41 | c.-44A>T | 5'UTR (SNP) | VAF 129/325 reads (40%) | catalogued as rs1255625353; called by muse, mutect2, varscan2
- BUD31 | c.94+597C>T | Intron (SNP) | VAF 36/97 reads (37%) | catalogued as rs774719860; called by muse, mutect2, varscan2
- CCDC78 | c.766-35del | Intron (DEL) | VAF 53/168 reads (32%) | catalogued as COSV53495457; called by mutect2, pindel, varscan2
- CDH2 | c.173-22639A>G | Intron (SNP) | VAF 55/124 reads (44%) | called by muse, mutect2, varscan2
- CDK5RAP1 | c.1248-67C>T | Intron (SNP) | VAF 32/51 reads (63%) | called by muse, mutect2, varscan2
- CEP164 | c.4096+17G>A | Intron (SNP) | VAF 146/399 reads (37%) | catalogued as rs777692922; called by muse, mutect2, varscan2
- CLTCL1 | c.4606-880C>T | Intron (SNP) | VAF 26/268 reads (10%) | catalogued as rs1246508006; called by muse, mutect2, varscan2
- COG8 | chr16:69323603 G>A | 3'Flank (SNP) | VAF 16/124 reads (13%) | catalogued as rs1038870868; called by muse, mutect2, varscan2
- COMMD4 | c.181+71del | Intron (DEL) | VAF 64/203 reads (32%) | catalogued as rs754738500; called by mutect2, pindel, varscan2
- CYLD | c.-29del | 5'UTR (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- CYP19A1 | c.1263+33C>T | Intron (SNP) | VAF 17/275 reads (6%) | called by muse, mutect2
- DAAM2 | c.-25T>C | 5'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- DNAH14 | c.9206-2503C>T | Intron (SNP) | VAF 99/377 reads (26%) | called by muse, mutect2, varscan2
- DNAH5 | c.7408-18del | Intron (DEL) | VAF 105/300 reads (35%) | catalogued as rs763542767; called by mutect2, varscan2
- DUSP13 | c.*707C>T | 3'UTR (SNP) | VAF 74/168 reads (44%) | catalogued as rs761085961; called by muse, mutect2, varscan2
- EMSY | c.1363+56del | Intron (DEL) | VAF 61/185 reads (33%) | called by mutect2, pindel, varscan2
- ENTPD4 | c.*2C>T | 3'UTR (SNP) | VAF 74/180 reads (41%) | called by muse, mutect2
- EPB41L2 | c.2043+1425G>A | Intron (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
- ETNK2 | c.519-714G>A | Intron (SNP) | VAF 104/370 reads (28%) | called by muse, mutect2, varscan2
- FADS6 | c.412-30C>T | Intron (SNP) | VAF 12/337 reads (4%) | called by muse, mutect2
- FAM183BP | n.833C>T | RNA (SNP) | VAF 94/247 reads (38%) | called by muse, mutect2, varscan2
- FAM20A | c.*742del | 3'UTR (DEL) | VAF 73/220 reads (33%) | catalogued as rs772873230; called by mutect2, varscan2
- FMO6P | n.1757C>T | RNA (SNP) | VAF 22/296 reads (7%) | catalogued as rs968322387; called by muse, mutect2
- FXYD6-FXYD2 | c.259+3374C>T | Intron (SNP) | VAF 22/127 reads (17%) | catalogued as rs1208027338; called by muse, mutect2, varscan2
- GRK2 | c.*979del | 3'UTR (DEL) | VAF 15/95 reads (16%) | catalogued as rs781487718, COSV57754474; called by mutect2, pindel, varscan2
- GSN | c.1740+89G>A | Intron (SNP) | VAF 106/322 reads (33%) | called by muse, mutect2, varscan2
- GVINP1 | n.5684G>A | RNA (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- HAGH | c.432+48G>A | Intron (SNP) | VAF 32/256 reads (13%) | catalogued as rs199897236; called by muse, mutect2, varscan2
- HAPLN4 | c.-41C>T | 5'UTR (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- HNRNPU | c.634+27G>T | Intron (SNP) | VAF 122/357 reads (34%) | called by muse, mutect2, varscan2
- HSD3B7 | c.532-31A>G | Intron (SNP) | VAF 233/589 reads (40%) | called by muse, mutect2, varscan2
- HSPA7 | n.1077A>C | RNA (SNP) | VAF 93/398 reads (23%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.711+38C>T | Intron (SNP) | VAF 132/368 reads (36%) | catalogued as rs773123197; called by muse, mutect2, varscan2
- IGHMBP2 | c.1235+1055G>A | Intron (SNP) | VAF 51/154 reads (33%) | catalogued as rs920434041; called by muse, mutect2, varscan2
- ILF3 | c.*195C>T | 3'UTR (SNP) | VAF 210/553 reads (38%) | catalogued as rs200123198, COSV51555736, COSV99139697; called by muse, mutect2, varscan2
- INTS8 | chr8:94823252 C>T | 5'Flank (SNP) | VAF 41/104 reads (39%) | catalogued as rs1164144607; called by muse, mutect2, varscan2
- KCNAB2 | c.119+9864G>A | Intron (SNP) | VAF 40/204 reads (20%) | catalogued as rs867008495; called by muse, mutect2, varscan2
- KDM4B | c.1115+691G>A | Intron (SNP) | VAF 68/187 reads (36%) | called by muse, mutect2, varscan2
69 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 69 other) are not listed here.
